Somatic mutation profile of tumor specimen 0DK3ED from CCDI case PBBXPV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,429 days).
Specimen 0DK3ED: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4d12110-c736-4416-b725-6cd50040adcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK3EQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a346c0d4-554a-4e83-916f-ff51a8d8336d

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OBSCN | c.14428C>T p.R4810W | Missense Mutation (SNP) | VAF 269/806 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs367669699; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 41/1322 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- OTUD1 | c.114C>G p.P38= | Silent (SNP) | VAF 52/497 reads (10%) | catalogued as rs939333612; called by muse, mutect2
- TAP2 | c.1734G>A p.A578= | Silent (SNP) | VAF 318/1065 reads (30%) | catalogued as rs543399235; called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 10/221 reads (5%) | called by muse, mutect2
